Gene-level copy-number profile of tumor specimen C3N-03180-02 from CPTAC case C3N-03180, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.1 years (19,399 days).
Specimen C3N-03180-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6b018589-7230-4925-a267-62ef84b2373b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03180-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,217 have no estimate.
https://portal.gdc.cancer.gov/files/93ba2bd7-7bd4-45ea-850d-832d0a533046

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3; copy number 2: 58,227; copy number 3: 126; copy number 4: 1; copy number 5: 1; copy number 10: 27; copy number 11: 2; copy number 13: 1; copy number 14: 2; copy number 19: 16.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 49 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,576,052–55,743,457, 27 genes, copy number 10: AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2.
- chr7:65,814,672–65,814,775, 1 gene, copy number 5: RNU6-912P.
- chr7:81,946,444–82,443,777, 1 gene, copy number 13 (within-gene range 2–13): CACNA2D1.
- chr12:68,610,855–68,671,901, 1 gene, copy number 19 (within-gene range 2–19): RAP1B.
- chr12:68,642,519–68,971,570, 15 genes, copy number 19: ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:83,661,009–84,449,878, 4 genes, copy number 11–14: AC093025.1, AC090679.2, AC090679.1, AC087888.1.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
